Gene-level copy-number profile of tumor specimen TCGA-29-1702-01A from TCGA case TCGA-29-1702, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 84.6 years (30,910 days).
Specimen TCGA-29-1702-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.5b8c15f0-5635-42d1-849d-66dacecfb6c0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-1702-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4f6af2a7-0886-48a3-b0da-441f25e77496

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 46; copy number 1: 2,545; copy number 2: 15,675; copy number 3: 18,648; copy number 4: 10,240; copy number 5: 9,823; copy number 6: 1,204; copy number 7: 271; copy number 8: 349; copy number 9: 199; copy number 10: 97; copy number 11: 164; copy number 12: 99; copy number 13: 137; copy number 14: 62; copy number 15: 116; copy number 17: 61; copy number 18: 11; copy number 19: 9; copy number 23: 49.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-29-1702-01A-01D-0559-01): tumor purity 0.97, ploidy 3.41, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 40 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:8,965,896–10,198,606, 25 genes: AC002091.2, AC002091.1, NTN1, AC005695.1, AC005695.3, STX8, AC005695.2, AC087501.1, AC087501.2, AC087501.3, AC087501.4, CFAP52, RPL19P18, AC118755.2, USP43, AC118755.1, AC027045.2, DHRS7C, AC027045.1, GSG1L2, AC027045.3, GLP2R, NPM1P45, RCVRN, GAS7.
- chr22:46,039,907–46,263,343, 15 genes: LINC00899, PRR34, AL121672.3, PRR34-AS1, MIRLET7BHG, AL121672.1, AL121672.2, MIR3619, MIRLET7A3, MIR4763, MIRLET7B, PPARA, FP325332.1, CDPF1, PKDREJ.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,624 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:35,268,709–39,788,865, 131 genes, copy number 8–10 (within-gene range 3–10) (broad region; genes not listed).
- chr2:153,337,705–153,421,957, 3 genes, copy number 8 (within-gene range 3–8): LINC01850, RPL23AP29, TUBAP13.
- chr2:153,446,813–153,478,762, 2 genes, copy number 8: AC012501.1, RPRM.
- chr2:175,072,250–178,830,802, 97 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr8:35,672,195–43,674,591, 189 genes, copy number 7–15 (broad region; genes not listed).
- chr8:55,067,585–60,868,028, 88 genes, copy number 13–23 (within-gene range 5–23) (broad region; genes not listed).
- chr8:62,143,311–63,014,000, 6 genes, copy number 8 (within-gene range 5–8): AC104852.1, AC023095.1, NKAIN3, AC018861.2, AC018861.1, AC090577.1.
- chr8:66,562,175–68,237,032, 29 genes, copy number 12–14 (within-gene range 3–14): MYBL1, VCPIP1, Y_RNA, C8orf44-SGK3, C8orf44, SGK3, PTTG3P, MCMDC2, SNHG6, SNORD87, TCF24, PPP1R42, AC110998.1, COPS5, CSPP1, RNA5SP268, AC087359.1, ARFGEF1, AC021321.2, AC021321.1, AC011037.1, CPA6, NACAP10, AC022874.1, NDUFS5P6, PREX2, AC011853.2, AC011853.1, Y_RNA.
- chr8:73,688,691–74,518,007, 21 genes, copy number 9 (within-gene range 5–9): AC022826.2, UBE2W, AC022826.1, RN7SL760P, AC022868.1, GYG1P1, ELOC, TMEM70, RPS20P21, DSTNP3, LY96, RNU6-1300P, AC087672.2, RPS3AP32, RNU6-1197P, AC087627.1, AC087672.1, JPH1, GDAP1, AC103952.1, Y_RNA.
- chr8:123,851,987–132,481,095, 119 genes, copy number 10–17 (within-gene range 4–17) (broad region; genes not listed).
- chr10:2,071,845–10,462,361, 153 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr10:52,450,874–55,746,908, 21 genes, copy number 7–17 (within-gene range 3–17): LNCAROD, MBL2, Y_RNA, AC073174.1, LINC02672, SNRPEP8, AC036101.1, RNA5SP318, AL365496.1, PCDH15, RNU6-687P, AL353784.1, NEFMP1, MIR548F1, AC051618.1, AC016822.1, AL355314.1, AL355314.2, MTRNR2L5, GAPDHP21, AC069545.1.
- chr12:38,078,529–38,589,812, 13 genes, copy number 12: AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B, AC087897.1, AC087897.2.
- chr12:57,762,334–65,826,997, 143 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr12:67,648,338–68,745,809, 29 genes, copy number 8 (within-gene range 6–8): DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39.
- chr12:71,839,707–72,728,844, 9 genes, copy number 9 (within-gene range 6–9): TBC1D15, MRS2P2, TPH2, AC090109.1, TRHDE, TRHDE-AS1, H3P35, CHCHD3P2, AC133480.1.
- chr12:75,020,969–75,984,015, 22 genes, copy number 7: AC073525.1, KCNC2, CAPS2-AS1, CCNG2P1, CAPS2, AC092552.1, AC121761.2, GLIPR1L1, GLIPR1L2, GLIPR1, AC121761.1, KRR1, AC078923.1, AC022507.1, AC078820.2, RPL10P13, SNORA70, AC078820.1, AC011611.6, RN7SL734P, AC011611.2, AC011611.1.
- chr12:76,351,797–76,853,696, 9 genes, copy number 7 (within-gene range 5–7): OSBPL8, AC107032.2, AC107032.3, RPL7AP9, YWHAQP7, AC107032.1, RPL7P43, AC093014.1, ZDHHC17.
- chr12:77,324,641–78,213,010, 1 gene, copy number 7 (within-gene range 5–7): NAV3.
- chr12:77,775,783–80,068,757, 26 genes, copy number 7: AC138331.1, AC073571.1, PRXL2AP1, LINC02424, AC128707.1, AC130415.1, AC079362.1, AC068993.1, AC068993.2, SYT1, AC090709.1, AC027288.3, MIR1252, AC027288.2, AC027288.1, NOP56P3, PAWR, AC073569.2, PPP1R12A, AC073569.3, AC073569.1, RNA5SP363, PPP1R12A-AS1, SNRPGP20, RPL7P38, RNU7-106P.
- chr12:80,102,899–80,103,333, 1 gene, copy number 7: AC078817.1.
- chr12:84,671,598–84,672,026, 1 gene, copy number 7: AC093027.1.
- chr12:105,704,203–106,140,033, 5 genes, copy number 7–9 (within-gene range 4–9): CASC18, ST13P3, AC011595.2, NUAK1, AC011595.1.
- chr15:71,147,650–71,189,064, 2 genes, copy number 7 (within-gene range 4–7): THSD4-AS1, HMGB1P6.
- chr15:87,325,829–87,703,852, 4 genes, copy number 7 (within-gene range 2–7): AC020687.1, RNU6-185P, LINC00052, AC103871.1.
- chr17:142,789–1,900,082, 61 genes, copy number 12 (within-gene range 1–12) (broad region; genes not listed).
- chr17:2,235,713–2,749,504, 30 genes, copy number 11: SMG6-IT1, AL450226.2, SRR, HNRNPA1P16, TSR1, SNORD91B, SNORD91A, SGSM2, AC006435.3, AC006435.2, MNT, AC006435.1, METTL16, AC006435.4, AC006435.5, RN7SL33P, EIF4A1P9, PAFAH1B1, SAMD11P1, AC015799.1, RN7SL608P, AC005696.2, AC005696.3, CLUH, MIR6776, AC005696.1, AC005696.4, CCDC92B, MIR1253, hsa-mir-1253.
- chr17:5,700,226–6,831,761, 31 genes, copy number 13 (within-gene range 2–13): AC135726.1, AC006236.1, AC007846.1, AC007846.2, WSCD1, AC104770.1, RNU6-1264P, BTF3P14, AC055872.2, AIPL1, AC055872.1, PIMREG, PITPNM3, Metazoa_SRP, KIAA0753, RNA5SP435, AC004706.3, TXNDC17, MED31, C17orf100, AC004706.1, MIR4520-1, MIR4520-2, ALOX15P1, SLC13A5, AC004706.2, RPL23AP73, XAF1, PRAL, FBXO39, TEKT1.
- chr17:7,281,718–8,119,047, 78 genes, copy number 8 (broad region; genes not listed).
- chr21:22,209,920–26,573,286, 61 genes, copy number 7–10 (within-gene range 6–10) (broad region; genes not listed).
- chr21:27,358,885–31,063,168, 91 genes, copy number 7–18 (broad region; genes not listed).
- chr21:32,628,759–33,072,413, 14 genes, copy number 9: SYNJ1, PAXBP1-AS1, PAXBP1, C21orf62-AS1, AP000280.2, C21orf62, AP000281.1, SNORA70, AP000281.2, AP000282.1, LINC01690, OLIG2, LINC00945, OLIG1.
- chr22:36,560,857–36,703,752, 1 gene, copy number 11 (within-gene range 5–11): CACNG2.
- chr22:36,703,918–39,320,389, 133 genes, copy number 11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,697. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
